Somatic mutation profile of tumor specimen MMRF_2240_1_BM_CD138pos (aliquot MMRF_2240_1_BM_CD138pos_T1_KHS5U_L09529) from MMRF case MMRF_2240, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,502 days).
Specimen MMRF_2240_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9478fbcd-bf03-4be4-aadf-7bc6dbeaa655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2240_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2240_1_PB_Whole_C3_KHS5U_L09530; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c07ad88-e707-4fbc-bc32-1d54abf330a4

The open-access MAF lists 102 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 24, Silent 13, Intron 9, 5'UTR 3, 5'Flank 2, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 52/126 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1996A>C p.K666Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754688962, COSV59206172, COSV59206856; ClinVar: likely pathogenic; called by muse, varscan2
- A1CF | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs377106588, COSV51023004; called by muse, mutect2, varscan2
- AADAT | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs1304752701; called by muse, mutect2
- BTBD8 | c.2407A>G p.S803G (on ENST00000636805 / NM_001376131.1; = p.S290G on NM_015237.4) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV64883508; called by muse, mutect2, varscan2
- CARS1 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1309224974; called by muse, mutect2, varscan2
- CENPJ | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs568294978, COSV67883067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.3608T>C p.V1203A (on ENST00000341947 / NM_080680.3; = p.V1096A on NM_080679.2) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs902373625; called by muse, mutect2, varscan2
- EPN1 | c.1663G>T p.G555C (on ENST00000270460 / NM_001321263.1; = p.G529C on NM_013333.3) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1443569122; called by muse, mutect2, varscan2
- H2BC4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 100/375 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV58415706; called by muse, mutect2, varscan2
- IGHV2-70 | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377155486; called by muse, varscan2
- IGHV3-33 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as rs746660718; called by muse, varscan2
- IGLV5-45 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | catalogued as rs766606257; called by muse, varscan2
- KCNN1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs1250560986; called by muse, mutect2
- LURAP1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV64338083; called by muse, mutect2
- MAMDC2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.547); catalogued as rs759771697, COSV65861573; called by muse, mutect2, varscan2
- PCDHA4 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV63541306; called by muse, mutect2, varscan2
- PDCD1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764200391, COSV57692360; called by muse, mutect2, varscan2
- RBP3 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781917479; called by muse, mutect2, varscan2
- SCARA3 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770196500; called by muse, mutect2, varscan2
- UFSP1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs776832355; called by muse, mutect2, varscan2
- WASF3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs772986602, COSV58971381; called by muse, mutect2, varscan2
- ZNF516 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV71586945; called by muse, mutect2, varscan2
- APBA1 | c.1378A>T p.I460F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BTBD2 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA2D4 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDAN1 | c.1460C>G p.A487G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP295 | c.7066A>G p.I2356V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRYBB2 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 99/195 reads (51%) | called by muse, mutect2, varscan2
- DGKQ | c.2593C>G p.L865V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DNAH11 | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- EPC2 | c.1080_1082del p.N361del | In Frame Del (DEL) | VAF 53/107 reads (50%) | called by mutect2, pindel, varscan2
- FPGT-TNNI3K | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FSIP2 | c.17444T>G p.V5815G | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- HMCN1 | c.14149G>A p.G4717R | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEXN | c.1603C>A p.Q535K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR2F1 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56A4 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- REG1B | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SAGE1 | c.1864T>A p.Y622N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPATC1 | c.131A>C p.Q44P | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- STK4 | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SUPT20H | c.40T>C p.Y14H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TARBP2 | c.412G>C p.V138L (on ENST00000266987 / NM_134323.2; = p.V117L on NM_004178.4) | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM21 | c.462+4A>T | Splice Region (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- TNFSF13B | c.549T>A p.N183K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TRIM31 | c.1263G>C p.E421D | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- UBQLN2 | c.1044T>G p.N348K | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT tolerated (0.95); PolyPhen benign (0.219); called by muse, varscan2
- ZMIZ1 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2
- DOT1L | c.2508G>C p.G836= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV67109869; called by muse, mutect2, varscan2
- GAB4 | c.1362G>A p.E454= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as COSV68755232; called by muse, varscan2
- HELZ | c.1782A>G p.Q594= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs747499913, COSV62379140; called by muse, mutect2, varscan2
- IGHV2-70D | c.213C>A p.R71= | Silent (SNP) | VAF 69/76 reads (91%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.36T>G p.T12= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs751633600; called by muse, mutect2, varscan2
- NDST4 | c.273C>T p.L91= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs1388696193, COSV52108678; called by muse, mutect2, varscan2
- OR4D1 | c.270G>A p.K90= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV52124606; called by muse, mutect2
- PROX2 | c.1161G>A p.P387= | Silent (SNP) | VAF 76/171 reads (44%) | catalogued as rs747207210, COSV71520075; called by muse, mutect2, varscan2
- RTP5 | c.411G>A p.R137= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs754671733; called by muse, varscan2
- SLC16A10 | c.1503A>C p.S501= | Silent (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- TP53BP1 | c.2791T>C p.L931= | Silent (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- TRIB3 | c.54G>T p.R18= | Silent (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- ZNF865 | c.1707G>A p.E569= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as rs1443778544; called by muse, mutect2, varscan2
- AC002519.1 | chr16:31794654 T>G | 3'Flank (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.*49C>G | 3'UTR (SNP) | VAF 76/272 reads (28%) | catalogued as COSV58419722; called by muse, mutect2, varscan2
- AMY2B | c.1101+46A>C | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- ANAPC7 | c.776+97G>A | Intron (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- AP000769.5 | chr11:65499050 T>G | 5'Flank (SNP) | VAF 7/45 reads (16%) | catalogued as rs751741864; called by muse, mutect2, varscan2
- ATF7IP2 | c.*850T>C | 3'UTR (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- BPGM | c.*480T>A | 3'UTR (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- C10orf88 | c.*302G>A | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- CNTN3 | c.*1542T>C | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- CYP7A1 | c.-5G>T | 5'UTR (SNP) | VAF 145/304 reads (48%) | called by muse, mutect2, varscan2
- DCAF5 | c.*760G>A | 3'UTR (SNP) | VAF 37/66 reads (56%) | catalogued as rs1335746864; called by muse, mutect2, varscan2
- DDHD1 | chr14:53153198 C>G | 5'Flank (SNP) | VAF 28/62 reads (45%) | called by muse, varscan2
- DHRS11 | c.358-1336G>A | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- DYRK2 | c.*20G>A | 3'UTR (SNP) | VAF 9/294 reads (3%) | called by muse, mutect2
- FABP4 | c.*313G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2
- HGF | c.625+926T>G | Intron (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- LMTK2 | c.*1498G>A | 3'UTR (SNP) | VAF 49/101 reads (49%) | catalogued as rs946564737; called by muse, mutect2, varscan2
- LY6E | c.*482G>A | 3'UTR (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- MARCHF10 | c.536-60G>A | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- MARCKS | c.*1A>C | 3'UTR (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- MCUR1 | c.*57G>C | 3'UTR (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- MDH1B | c.*144T>C | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- MMP16 | c.*8711G>T | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MTUS2 | c.3118-11194T>C | Intron (SNP) | VAF 62/123 reads (50%) | called by muse, mutect2, varscan2
- NTSR1 | c.*246C>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | catalogued as rs937229356; called by muse, mutect2, varscan2
- PLCXD3 | c.-97C>G | 5'UTR (SNP) | VAF 5/117 reads (4%) | called by muse, mutect2
- PTK2 | c.2946+1951T>C | Intron (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- RUNX1 | c.*1364G>A | 3'UTR (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- SEMA5A | c.*2486G>A | 3'UTR (SNP) | VAF 36/82 reads (44%) | catalogued as rs1419646375, COSV66783765; called by muse, mutect2, varscan2
- SNAP29 | c.*2457G>A | 3'UTR (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- SREK1IP1 | c.*3316A>G | 3'UTR (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.-354T>C | 5'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs1564625783; called by mutect2, varscan2
- TBC1D1 | c.1077+64T>G | Intron (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- TMEM59 | c.390+1039T>G | Intron (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- TNKS1BP1 | c.*260T>C | 3'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- TRIM31 | c.*566A>G | 3'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as rs1168686021; called by mutect2, varscan2
- UQCRB | c.*4741T>C | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- WWC2 | c.*5034C>A | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ZBTB6 | c.*211T>G | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
